Somatic mutation profile of tumor specimen C3L-00790-01 (aliquot CPT0065690009) from CPTAC case C3L-00790, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 44.7 years (16,335 days).
Specimen C3L-00790-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 086aa8f2-3d5c-47b2-9b60-8936cae42c9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00790-31 (Blood Derived Normal), aliquot CPT0067650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf46edb1-3ad8-4b90-82e5-a880d27b6c96

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 6, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, 5'UTR 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACIN1 | c.2375T>C p.I792T | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1198390322; called by muse, mutect2
- MRFAP1L1 | c.187A>G p.M63V | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs754524317; called by muse, mutect2, varscan2
- PBRM1 | c.1251C>G p.Y417* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99968106; called by muse, mutect2, varscan2
- SRSF4 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs377019095; called by muse, mutect2, varscan2
- ADAM28 | c.136del p.E46Sfs*12 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel
- ADRA2A | c.1279T>C p.F427L | Missense Mutation (SNP) | VAF 50/526 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CD84 | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | called by mutect2, varscan2
- CSMD3 | c.8613G>A p.V2871= (on ENST00000297405 / NM_001363185.1; = p.V2702= on NM_052900.3) | Splice Region (SNP) | VAF 27/250 reads (11%) | called by muse, mutect2, varscan2
- FBXO47 | c.1096_1097insT p.E366Vfs*10 | Frame Shift Ins (INS) | VAF 4/44 reads (9%) | called by mutect2, pindel
- FGF16 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KANSL1L | c.1402T>G p.L468V | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- MROH7 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBM12B | c.1664C>G p.P555R | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- SBK1 | c.913C>T p.P305S | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SEMA6C | c.1531A>G p.I511V | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SETBP1 | c.2411C>A p.T804N | Missense Mutation (SNP) | VAF 73/713 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SETD2 | c.5290C>T p.Q1764* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- SLC9A5 | c.1766T>C p.V589A | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- TNNC2 | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.92); called by muse, varscan2
- VHL | c.300del p.L101Cfs*58 | Frame Shift Del (DEL) | VAF 72/512 reads (14%) | called by mutect2, pindel, varscan2
- ZNF782 | c.498T>G p.N166K | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, mutect2
- ABHD17A | c.183C>T p.G61= | Silent (SNP) | VAF 96/509 reads (19%) | catalogued as rs769877762; called by muse, varscan2
- FIS1 | c.393C>A p.G131= | Silent (SNP) | VAF 63/296 reads (21%) | catalogued as COSV56191914; called by muse, mutect2, varscan2
- FLVCR1 | c.1149G>T p.V383= | Silent (SNP) | VAF 26/222 reads (12%) | called by muse, mutect2, varscan2
- FRMD4B | c.2025C>T p.S675= | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2
- GLIS1 | c.882C>T p.C294= | Silent (SNP) | VAF 36/332 reads (11%) | called by muse, mutect2, varscan2
- RPS7 | c.279C>A p.V93= | Silent (SNP) | VAF 86/428 reads (20%) | called by muse, mutect2, varscan2
- EIF2AK3 | c.2037-15T>A | Intron (SNP) | VAF 18/235 reads (8%) | called by muse, mutect2
- PANK3 | c.936+484C>T | Intron (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- PLCE1 | c.-48C>T | 5'UTR (SNP) | VAF 16/105 reads (15%) | catalogued as rs554052819; called by muse, mutect2, varscan2
- TGIF1 | c.-72C>T | 5'UTR (SNP) | VAF 52/521 reads (10%) | catalogued as COSV57907159; called by muse, mutect2, varscan2
